Somatic mutation profile of tumor specimen 2dc28da8-7ff1-4b9b-b5bd-17cc25 (aliquot 2dc28da8-7ff1-4b9b-b5bd-17cc25_D6_1) from CPTAC case 02OV035, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 2dc28da8-7ff1-4b9b-b5bd-17cc25: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f664801c-c11c-4abf-b7dd-4354959101fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 06ac6957-d65b-4d29-b412-9dd1e2 (Blood Derived Normal), aliquot 06ac6957-d65b-4d29-b412-9dd1e2_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a386a22a-d986-43db-bd93-9214305222d2

The open-access MAF lists 61 somatic variants for this specimen: 45 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 13, Nonsense Mutation 4, Intron 3, Frame Shift Del 2, Splice Site 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 496/538 reads (92%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, varscan2
- ASXL1 | c.2668C>G p.L890V | Missense Mutation (SNP) | VAF 138/824 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.041); catalogued as COSV60109649; called by muse, mutect2, varscan2
- AXIN1 | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as rs768902926; called by muse, mutect2, varscan2
- IGF1 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 76/229 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61033073; called by muse, mutect2, varscan2
- KIAA2026 | c.5147G>A p.G1716E | Missense Mutation (SNP) | VAF 78/345 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs893340804; called by muse, mutect2, varscan2
- MC1R | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as rs774680166, COSV59626514; called by muse, mutect2, varscan2
- PHF21B | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 51/61 reads (84%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs776556694, COSV57561430; called by muse, mutect2, varscan2
- PROCA1 | c.656G>A p.R219H (on ENST00000439862 / NM_001366301.1; = p.R191H on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1329152439; called by muse, mutect2, varscan2
- SH2B1 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1198783948, COSV100451242, COSV59461283; called by muse, mutect2, varscan2
- SLC44A4 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.305); catalogued as rs549331790; called by muse, varscan2
- TEX26 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV104431503, COSV66839927; called by muse, mutect2, varscan2
- TSC2 | c.3436G>A p.A1146T | Missense Mutation (SNP) | VAF 205/349 reads (59%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.98); catalogued as rs1437771620; called by muse, mutect2, varscan2
- WDR70 | c.1598-1G>C p.X533_splice | Splice Site (SNP) | VAF 24/212 reads (11%) | catalogued as rs781643870; called by muse, mutect2, varscan2
- ADGRB3 | c.4118T>G p.M1373R | Missense Mutation (SNP) | VAF 111/291 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- APLP2 | c.1486T>A p.Y496N | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- C1orf158 | c.250A>T p.T84S | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- CEP170 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 88/322 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- CNTNAP4 | c.3914A>G p.E1305G | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL6A1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 151/510 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRACDL | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- DCTD | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DEPDC1 | c.1618C>T p.Q540* | Nonsense Mutation (SNP) | VAF 53/240 reads (22%) | called by muse, mutect2, varscan2
- DNAH12 | c.4059T>G p.I1353M (on ENST00000351747; = p.I1376M on NM_001366028.2) | Missense Mutation (SNP) | VAF 98/204 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCRLB | c.1013_1017del p.G338Afs*127 | Frame Shift Del (DEL) | VAF 105/424 reads (25%) | called by mutect2, pindel, varscan2
- FKBP15 | c.254+5G>T | Splice Region (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- GPER1 | c.1048C>A p.R350S | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- H1-2 | c.32C>G p.A11G | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- LYPD1 | c.409T>A p.F137I | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MAPK4 | c.1436C>T p.T479M | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NLRP1 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- NPIPB11 | c.359C>G p.S120C | Missense Mutation (SNP) | VAF 69/279 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- NR2E1 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 92/246 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- PARP4 | c.4128G>T p.W1376C | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PRKCB | c.1397A>T p.D466V | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SELL | c.740C>G p.T247S (on ENST00000650983; = p.T234S on NM_000655.5) | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT tolerated (0.91); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SEMA4B | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- SIPA1L1 | c.2919T>G p.I973M | Missense Mutation (SNP) | VAF 103/235 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- SMYD2 | c.284T>A p.V95D | Missense Mutation (SNP) | VAF 21/362 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.061); called by muse, mutect2
- SNTG1 | c.1428del p.H477Tfs*11 | Frame Shift Del (DEL) | VAF 71/264 reads (27%) | called by mutect2, pindel, varscan2
- STRN3 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.552); called by muse, mutect2
- TRAPPC3 | c.368C>A p.S123* | Nonsense Mutation (SNP) | VAF 42/162 reads (26%) | called by muse, mutect2, varscan2
- TRIM33 | c.1059G>T p.E353D | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UBXN1 | c.294G>T p.M98I | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2
- VEZT | c.60_83del p.L20_D27del | In Frame Del (DEL) | VAF 22/62 reads (35%) | called by mutect2, pindel, varscan2
- WDR72 | c.2388A>C p.K796N | Missense Mutation (SNP) | VAF 166/387 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by mutect2, varscan2
- ADAMTS7 | c.195C>T p.R65= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as COSV66307012; called by muse, mutect2, varscan2
- ADCY1 | c.822C>T p.N274= | Silent (SNP) | VAF 60/271 reads (22%) | catalogued as rs555902826, COSV52037980; called by muse, mutect2, varscan2
- CYP3A43 | c.726A>C p.P242= | Silent (SNP) | VAF 45/142 reads (32%) | called by muse, mutect2, varscan2
- CYP4V2 | c.1422G>C p.V474= | Silent (SNP) | VAF 22/282 reads (8%) | called by muse, mutect2
- HOXB5 | c.336C>G p.P112= | Silent (SNP) | VAF 79/151 reads (52%) | catalogued as rs770794410; called by muse, mutect2, varscan2
- KCNG4 | c.1089C>T p.T363= | Silent (SNP) | VAF 92/207 reads (44%) | catalogued as rs781250021; called by muse, mutect2, varscan2
- MYH8 | c.1167T>C p.Y389= | Silent (SNP) | VAF 35/383 reads (9%) | called by muse, mutect2
- NBEA | c.2070G>A p.Q690= | Silent (SNP) | VAF 27/77 reads (35%) | called by muse, mutect2, varscan2
- PPP1R16B | c.1614G>A p.T538= | Silent (SNP) | VAF 16/22 reads (73%) | catalogued as rs148651333; called by muse, mutect2, varscan2
- RYR2 | c.12648G>A p.A4216= | Silent (SNP) | VAF 150/535 reads (28%) | catalogued as rs781557399, COSV63659303; ClinVar: likely benign / benign; called by muse, varscan2
- TEX55 | c.888C>A p.G296= | Silent (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- TRPC7 | c.240C>T p.N80= | Silent (SNP) | VAF 68/78 reads (87%) | catalogued as rs372900766, COSV61456123; called by muse, mutect2, varscan2
- VPS4A | c.243C>A p.G81= | Silent (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
- AC002511.3 | n.325-21C>A | Intron (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- CRIP1 | c.136-22_136-18del | Intron (DEL) | VAF 98/233 reads (42%) | called by mutect2, pindel, varscan2
- SATB2 | c.1173+144C>T | Intron (SNP) | VAF 19/66 reads (29%) | catalogued as rs778523083, COSV53491608; called by muse, mutect2, varscan2
